TCGA case TCGA-Z6-A9VB — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c2837d4-bd2c-46f7-9e22-683b82a16350

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 53 years; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 53.3 years (19,470 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 40 days; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 15 days; Disease response: Tumor Free.
- Days to follow up: 40 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 159 cm; BMI: 24.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-Z6-A9VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-Z6-A9VB-01A-02-TSB: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-Z6-A9VB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-Z6-A9VB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Cancer procurement city: Saint Petersburg; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Squamous Cell Carcinoma.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 40 days; disease-specific survival: no event (censored), 40 days; disease-free interval: no event (censored), 40 days; progression-free interval: no event (censored), 40 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-Z6-A9VB-01A-21D-A37B-01): tumor purity 0.72, ploidy 2.06, whole-genome doublings 0.
